Somatic mutation profile of tumor specimen TCGA-2Y-A9H4-01A (aliquot TCGA-2Y-A9H4-01A-11D-A382-10) from TCGA case TCGA-2Y-A9H4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.7 years (25,096 days).
Specimen TCGA-2Y-A9H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46ce8f8f-b114-49c1-8f87-803fcd3901ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H4-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H4-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7fd2a6f-f399-4c28-9ae9-3cb5b67eadd6

The open-access MAF lists 74 somatic variants for this specimen: 57 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 15, Frame Shift Ins 3, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.267del p.S90Pfs*33 | Frame Shift Del (DEL) | VAF 55/107 reads (51%) | catalogued as rs587783062; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ACADM | c.26G>T p.C9F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV63720167, COSV63720864; called by muse, mutect2, varscan2
- ADAMTS20 | c.1377C>A p.Y459* | Nonsense Mutation (SNP) | VAF 28/57 reads (49%) | catalogued as COSV101240245; called by muse, mutect2
- ADAMTS20 | c.1375T>A p.Y459N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV101240246; called by muse, mutect2
- ADCY3 | c.143G>C p.C48S | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV99569049; called by muse, mutect2, varscan2
- BOP1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100266085; called by muse, mutect2
- CEP290 | c.3496G>T p.V1166F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100469692; called by muse, mutect2, varscan2
- CHSY3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); catalogued as COSV100519884; called by muse, mutect2, varscan2
- CISH | c.20+1G>A p.X7_splice | Splice Site (SNP) | VAF 54/174 reads (31%) | catalogued as COSV100811794; called by muse, mutect2, varscan2
- CLK4 | c.568A>C p.I190L | Missense Mutation (SNP) | VAF 79/124 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100309101, COSV60318311; called by muse, mutect2, varscan2
- DAAM1 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759867723, COSV62839582; called by muse, mutect2, varscan2
- EIF2AK4 | c.1100A>G p.K367R | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV99775324; called by muse, mutect2, varscan2
- FGA | c.2072A>G p.D691G | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100120694; called by muse, varscan2
- FGA | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV100120560, COSV100120695; called by muse, mutect2, varscan2
- GFRAL | c.543C>A p.N181K | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100475832, COSV61231311; called by muse, varscan2
- GPIHBP1 | c.379A>T p.T127S | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100427396; called by muse, mutect2, varscan2
- HPS3 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99937611; called by muse, mutect2, varscan2
- HS3ST1 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99136735, COSV99136992; called by muse, mutect2, varscan2
- IRS4 | c.1479G>T p.W493C | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV100929703; called by muse, mutect2, varscan2
- KLHL40 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as COSV55133472; called by muse, mutect2, varscan2
- LIPH | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99956296; called by muse, mutect2, varscan2
- MUC17 | c.10704G>T p.M3568I | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV100074909; called by muse, mutect2, varscan2
- NBEA | c.1208T>G p.F403C | Missense Mutation (SNP) | VAF 129/321 reads (40%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.957); catalogued as COSV100083740; called by muse, mutect2, varscan2
- NETO1 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100199485, COSV100199646; called by muse, mutect2, varscan2
- OR2L3 | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100742043; called by muse, mutect2, varscan2
- OR4S2 | c.742T>C p.F248L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV100412788, COSV56746406; called by muse, mutect2, varscan2
- OR6X1 | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1456308576, COSV60009452; called by muse, mutect2, varscan2
- OR7A5 | c.839T>A p.V280E | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100457928; called by muse, mutect2, varscan2
- OR8D4 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58430158; called by muse, mutect2, varscan2
- OTOA | c.2113C>T p.H705Y (on ENST00000286149; = p.H691Y on NM_144672.4) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs755029973, COSV99625679; called by muse, mutect2, varscan2
- PAPPA | c.3514G>A p.A1172T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758150326, COSV100075185; called by muse, mutect2, varscan2
- PCDHA12 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.087); catalogued as rs782552942, COSV99165576; called by muse, mutect2, varscan2
- PCDHGA8 | c.1297T>C p.S433P | Missense Mutation (SNP) | VAF 57/213 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); catalogued as COSV99546068; called by muse, mutect2, varscan2
- PIAS3 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.581); catalogued as rs1553735631, COSV100992755; called by muse, mutect2, varscan2
- PLCXD3 | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100126261; called by muse, mutect2, varscan2
- RELA | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100425932; called by muse, mutect2, varscan2
- RHBDL1 | c.984G>T p.M328I (on ENST00000219551 / NM_001318733.2; = p.M263I on NM_001278720.2) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV99555973; called by muse, mutect2, varscan2
- RNMT | c.939T>A p.Y313* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV100054921; called by muse, mutect2, varscan2
- RYR3 | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.268); catalogued as COSV101214267; called by muse, mutect2, varscan2
- SACS | c.7102G>T p.A2368S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101207700, COSV66543147; called by muse, mutect2, varscan2
- SAMD4A | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV99200815; called by muse, mutect2, varscan2
- SIRPG | c.934A>T p.S312C | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99403958; called by muse, mutect2, varscan2
- SNX16 | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100629698; called by muse, mutect2, varscan2
- TAF4 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV53337697, COSV99434964; called by muse, mutect2, varscan2
- TDRD6 | c.2397A>C p.K799N | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100288275; called by muse, mutect2
- TJP3 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1224652629, COSV99515858, COSV99516438; called by muse, mutect2, varscan2
- TMEFF1 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100614963; called by muse, mutect2, varscan2
- TNMD | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 81/92 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs761145360, COSV65976754; called by muse, mutect2, varscan2
- TTC3 | c.3545G>A p.R1182K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.97); catalogued as COSV100695999; called by muse, mutect2, varscan2
- VRTN | c.505A>T p.S169C | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99832472; called by muse, mutect2, varscan2
- VWA7 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1418013691, COSV100991966; called by muse, mutect2, varscan2
- DNAJC14 | c.133del p.T45Lfs*211 | Frame Shift Del (DEL) | VAF 42/143 reads (29%) | called by mutect2, pindel, varscan2
- HNRNPA1 | c.24dup p.E9Rfs*16 | Frame Shift Ins (INS) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- PTPRK | c.2529dup p.L844Sfs*9 (on ENST00000368215 / NM_001291984.2; = p.L845Sfs*9 on NM_002844.4) | Frame Shift Ins (INS) | VAF 35/111 reads (32%) | called by mutect2, pindel, varscan2
- ST8SIA6 | c.825del p.N276Tfs*29 | Frame Shift Del (DEL) | VAF 28/198 reads (14%) | called by mutect2, pindel, varscan2
- UPF3B | c.625-1_627del p.X209_splice | Splice Site (DEL) | VAF 23/29 reads (79%) | called by mutect2, pindel, varscan2
- USP34 | c.1193dup p.L398Ffs*13 | Frame Shift Ins (INS) | VAF 106/352 reads (30%) | called by mutect2, pindel, varscan2
- BTAF1 | c.2865A>T p.S955= | Silent (SNP) | VAF 4/85 reads (5%) | catalogued as COSV99795755; called by muse, mutect2
- GNA14 | c.273C>T p.D91= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV100503367; called by muse, mutect2, varscan2
- GUCY2C | c.384C>T p.T128= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV53789200; called by muse, mutect2, varscan2
- INTS13 | c.2010G>A p.Q670= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV99677587; called by muse, mutect2, varscan2
- MED24 | c.1248T>C p.T416= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100673331; called by muse, mutect2, varscan2
- MUC5B | c.10356C>A p.A3452= | Silent (SNP) | VAF 105/258 reads (41%) | catalogued as rs1407614963, COSV101500717; called by muse, mutect2, varscan2
- MXRA5 | c.6789G>T p.V2263= | Silent (SNP) | VAF 63/88 reads (72%) | catalogued as COSV99479008; called by muse, mutect2, varscan2
- MYOF | c.330A>G p.K110= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV100826094; called by muse, mutect2
- NBEA | c.7317C>T p.Y2439= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV100083742; called by muse, mutect2, varscan2
- NTSR2 | c.1209G>A p.G403= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs150650740; called by muse, mutect2, varscan2
- OAF | c.168C>T p.S56= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV100202997; called by muse, mutect2, varscan2
- PRRG4 | c.615A>G p.P205= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV99141424; called by muse, mutect2, varscan2
- RAPGEF6 | c.3864A>G p.L1288= | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as rs373104489; called by muse, mutect2, varscan2
- SELPLG | c.237G>A p.E79= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs749995403, COSV99947658; called by muse, mutect2, varscan2
- SPESP1 | c.171A>G p.K57= | Silent (SNP) | VAF 81/201 reads (40%) | catalogued as COSV99534679; called by muse, mutect2, varscan2
- MIR512-1 | n.8C>A | RNA (SNP) | VAF 146/429 reads (34%) | called by muse, mutect2, varscan2
- NPR3 | c.*3287T>A | 3'UTR (SNP) | VAF 65/230 reads (28%) | catalogued as COSV99423783; called by muse, mutect2, varscan2
